Somatic mutation profile of tumor specimen MP2PRT-PARXEB-TMP1-A (aliquot MP2PRT-PARXEB-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARXEB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,794 days).
Specimen MP2PRT-PARXEB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4680303a-0112-465d-a7d0-be6ae902346d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARXEB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARXEB-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b6e996c-120c-4092-a550-0185f38c0760

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Nonsense Mutation 3, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 72/388 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD30A | c.2786G>A p.R929H (on ENST00000611781; = p.R873H on NM_052997.2) | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs369021080; called by muse, mutect2
- NAV2 | c.2269C>T p.R757W (on ENST00000396087 / NM_001244963.2; = p.R734W on NM_145117.5) | Missense Mutation (SNP) | VAF 74/430 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148513005; called by muse, mutect2, varscan2
- PDZRN3 | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 50/278 reads (18%) | catalogued as rs1033690271, COSV55195401; called by muse, mutect2, varscan2
- TRIM29 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs367764612; called by muse, mutect2
- ADAM2 | c.1172A>T p.K391M | Missense Mutation (SNP) | VAF 66/384 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ANKRD24 | c.2784G>T p.E928D | Missense Mutation (SNP) | VAF 171/859 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- AWAT2 | c.605T>A p.L202* | Nonsense Mutation (SNP) | VAF 127/714 reads (18%) | called by muse, mutect2, varscan2
- FAT4 | c.11838C>A p.C3946* | Nonsense Mutation (SNP) | VAF 53/384 reads (14%) | called by muse, mutect2, varscan2
- GP2 | c.951C>A p.N317K (on ENST00000381362 / NM_001007240.3; = p.N314K on NM_001502.4) | Missense Mutation (SNP) | VAF 79/378 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- IL13RA1 | c.331A>T p.S111C | Missense Mutation (SNP) | VAF 70/460 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR8B3 | c.203T>C p.F68S | Missense Mutation (SNP) | VAF 45/294 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- COL22A1 | c.4470G>A p.A1490= | Silent (SNP) | VAF 63/314 reads (20%) | catalogued as rs748451665, COSV57341187; called by muse, mutect2, varscan2
- MOCS1 | c.124-43C>T | Intron (SNP) | VAF 79/555 reads (14%) | catalogued as rs374459152; called by muse, mutect2, varscan2
